Somatic mutation profile of tumor specimen ALCH-B1X0-TTP1-A (aliquot ALCH-B1X0-TTP1-A-2-0-D-A76N-36) from ALCHEMIST case ALCH-B1X0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.6 years (25,796 days).
Specimen ALCH-B1X0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9aabd2f-e2de-495c-9f68-4a9366930c64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1X0-NB1-A (Blood Derived Normal), aliquot ALCH-B1X0-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf7a055d-4697-45c4-b15d-2f2edc1ff927

The open-access MAF lists 36 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Nonsense Mutation 3, Intron 2, Splice Region 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 91/655 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13576C>T p.Q4526* | Nonsense Mutation (SNP) | VAF 35/396 reads (9%) | catalogued as rs1380530422, COSV68948871; called by muse, mutect2
- ACTN3 | c.2228A>G p.N743S | Missense Mutation (SNP) | VAF 43/371 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs771526492; called by muse, mutect2, varscan2
- CCDC88B | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 39/767 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs999112943; called by muse, mutect2
- CSMD1 | c.6565T>G p.F2189V (on ENST00000520002; = p.F2188V on NM_033225.6) | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV59289644; called by muse, mutect2
- FSCN1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1212305702, COSV61017342; called by muse, mutect2, varscan2
- OPRM1 | c.377A>G p.Q126R | Missense Mutation (SNP) | VAF 60/456 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1312299099; called by muse, mutect2, varscan2
- PKHD1L1 | c.2066A>G p.Y689C | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1469054589; called by muse, mutect2, varscan2
- PPP2R2C | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as rs1175331044, COSV59448324; called by muse, mutect2, varscan2
- USE1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1441769191; called by muse, mutect2
- C17orf64 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COIL | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 49/454 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPZ | c.1561G>T p.A521S (on ENST00000360986 / NM_001014447.3; = p.A510S on NM_003652.3) | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYST | c.907A>C p.S303R | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTERF1 | c.610T>G p.F204V | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKX2-1 | c.970dup p.A324Gfs*85 | Frame Shift Ins (INS) | VAF 28/196 reads (14%) | called by mutect2, pindel, varscan2
- PEX16 | c.320T>A p.V107E | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PTPRT | c.801T>A p.C267* | Nonsense Mutation (SNP) | VAF 29/221 reads (13%) | called by muse, mutect2, varscan2
- ROBO1 | c.2917C>T p.Q973* | Nonsense Mutation (SNP) | VAF 20/405 reads (5%) | called by muse, mutect2
- SPTAN1 | c.3908A>T p.H1303L | Missense Mutation (SNP) | VAF 75/712 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SYNE1 | c.9269G>C p.C3090S (on ENST00000367255 / NM_182961.4; = p.C3097S on NM_033071.3) | Missense Mutation (SNP) | VAF 89/649 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCTN1 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 60/600 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TPP2 | c.265A>C p.I89L | Missense Mutation (SNP) | VAF 99/880 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UNC5D | c.1764C>A p.P588= | Splice Region (SNP) | VAF 43/382 reads (11%) | called by muse, varscan2
- USP2 | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CHI3L2 | c.283C>T p.L95= | Silent (SNP) | VAF 38/345 reads (11%) | called by muse, mutect2, varscan2
- CLIP1 | c.498C>T p.N166= | Silent (SNP) | VAF 72/483 reads (15%) | called by muse, mutect2, varscan2
- ENPP6 | c.711T>A p.I237= | Silent (SNP) | VAF 41/291 reads (14%) | called by muse, mutect2, varscan2
- MADD | c.327G>A p.K109= | Silent (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2, varscan2
- NPAS4 | c.1086C>A p.L362= | Silent (SNP) | VAF 36/326 reads (11%) | catalogued as COSV60651881; called by muse, mutect2, varscan2
- OSBPL7 | c.141T>A p.P47= | Silent (SNP) | VAF 8/252 reads (3%) | called by muse, mutect2
- SFXN5 | c.51C>T p.S17= | Silent (SNP) | VAF 45/438 reads (10%) | called by muse, mutect2, varscan2
- STS | c.1689G>A p.L563= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as rs1425819185; called by muse, mutect2
- HAUS7 | c.961-494C>T | Intron (SNP) | VAF 104/391 reads (27%) | called by muse, mutect2, varscan2
- MED21 | c.*1755del | 3'UTR (DEL) | VAF 45/405 reads (11%) | called by pindel, varscan2
- TYK2 | c.2467-44G>A | Intron (SNP) | VAF 28/146 reads (19%) | catalogued as rs1389431065; called by muse, mutect2, varscan2
